Gene-level copy-number profile of tumor specimen TCGA-FP-7829-01A from TCGA case TCGA-FP-7829, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.9 years (25,534 days).
Specimen TCGA-FP-7829-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.0afaf59f-348c-4065-9ba2-5c792ab77e1d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FP-7829-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c94d640a-4771-427e-8fbf-d472e771da14

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 1,054; copy number 2: 14,671; copy number 3: 25,855; copy number 4: 12,262; copy number 5: 3,933; copy number 6: 1,148; copy number 7: 294; copy number 8: 405; copy number 9: 21; copy number 10: 20; copy number 11: 31; copy number 12: 26; copy number 16: 31; copy number 18: 22; copy number 20: 8; copy number 22: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FP-7829-01A-11D-2052-01): tumor purity 0.73, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr7:111,091,006–111,125,454, 1 gene: LRRN3.
- chr21:14,108,813–15,014,430, 13 genes (within-gene range 0–2): LIPI, ERLEC1P1, RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1, AF127936.1, POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 870 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,511,795–8,513,021, 2 genes, copy number 7: AL096855.1, AL096855.2.
- chr4:1,009,936–3,501,473, 72 genes, copy number 7 (broad region; genes not listed).
- chr4:6,178,186–10,054,936, 121 genes, copy number 8–10 (within-gene range 4–10) (broad region; genes not listed).
- chr4:11,368,827–11,467,802, 5 genes, copy number 7 (within-gene range 3–7): MIR572, RNPS1P1, HS3ST1, RNA5SP156, AC006230.1.
- chr4:24,517,441–24,584,554, 3 genes, copy number 8: DHX15, MIR573, RN7SL16P.
- chr4:69,588,417–78,008,688, 162 genes, copy number 7–20 (within-gene range 3–20) (broad region; genes not listed).
- chr5:7,980,146–10,082,772, 47 genes, copy number 7: RNU1-76P, AC116361.1, AC091941.1, AC091912.2, AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4.
- chr5:10,971,836–11,904,446, 1 gene, copy number 7 (within-gene range 4–7): CTNND2.
- chr5:12,297,399–13,190,677, 7 genes, copy number 7: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1.
- chr5:14,143,342–21,032,845, 107 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr5:39,284,140–44,066,731, 85 genes, copy number 8–18 (broad region; genes not listed).
- chr6:32,730,758–32,896,490, 13 genes, copy number 8: HLA-DQB3, HLA-DQA2, MIR3135B, HLA-DQB2, HLA-DOB, AL669918.1, TAP2, PSMB8, PSMB8-AS1, PSMB9, TAP1, PPP1R2P1, HLA-Z.
- chr6:40,713,411–48,068,689, 194 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr6:55,327,469–60,546,660, 39 genes, copy number 8 (within-gene range 5–8): GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1, AC244258.1.
- chr6:63,211,446–63,583,587, 12 genes, copy number 22: FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2.

Autosomal genes at a single copy (total copy number 1): 1,054. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
